Gene-level copy-number profile of tumor specimen TCGA-62-8399-01A from TCGA case TCGA-62-8399, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 62.8 years (22,952 days).
Specimen TCGA-62-8399-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.4ec66dd9-d216-48c8-8a90-30a609a8e62c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-62-8399-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e1899529-1646-4d9c-9f96-cc9c62cee49a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 50; copy number 2: 2,860; copy number 3: 9,023; copy number 4: 26,419; copy number 5: 1,130; copy number 6: 10,100; copy number 7: 6,486; copy number 8: 2,951; copy number 9: 63; copy number 11: 618; copy number 12: 22; copy number 14: 92.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-62-8399-01A-21D-2322-01): tumor purity 0.5, ploidy 2.44, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 795 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:35,263,711–40,611,053, 85 genes, copy number 9–12 (within-gene range 8–12) (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 11–14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 50. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
